Somatic mutation profile of tumor specimen TCGA-TS-A7OU-01B (aliquot TCGA-TS-A7OU-01B-11D-A39R-32) from TCGA case TCGA-TS-A7OU, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 56.8 years (20,747 days).
Specimen TCGA-TS-A7OU-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12349c36-231b-4f5e-8e5b-496ff6b2b87e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TS-A7OU-10A (Blood Derived Normal), aliquot TCGA-TS-A7OU-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee0de133-b464-469d-9a4b-63340a795902

The open-access MAF lists 41 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Intron 2, In Frame Del 1, Translation Start Site 1, Frame Shift Ins 1, Frame Shift Del 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 18/44 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC86 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs775638540; called by muse, mutect2, varscan2
- CHRNA2 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs796052307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMD1 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs148792644; called by muse, mutect2, varscan2
- GRIN2C | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs763318563; called by muse, mutect2, varscan2
- IL1R2 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs776757109, COSV60206860; called by muse, mutect2, varscan2
- MMRN2 | c.2453C>T p.A818V | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV64401119; called by muse, mutect2, varscan2
- POM121L12 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV68694351; called by muse, mutect2, varscan2
- SLC16A6 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555750107; called by muse, mutect2, varscan2
- SLIT3 | c.3679G>C p.V1227L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as rs1243874355; called by muse, mutect2, varscan2
- SNRNP200 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs754858849, COSV60492831; called by muse, mutect2, varscan2
- ST8SIA2 | c.840C>T p.R280= | Splice Region (SNP) | VAF 26/67 reads (39%) | catalogued as rs541352424, COSV51568080; called by muse, mutect2, varscan2
- SYNE1 | c.3829C>A p.H1277N (on ENST00000367255 / NM_182961.4; = p.H1284N on NM_033071.3) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.177); catalogued as rs1214631526; called by muse, varscan2
- USP45 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1462309680; called by muse, mutect2, varscan2
- APOA1 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CCDC120 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CMTM7 | c.517G>C p.A173P | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- DLGAP3 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.365); called by muse, mutect2
- DNAH5 | c.562G>C p.G188R | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EXOC3L1 | c.559G>C p.V187L | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- F5 | c.1370_1375del p.D457_E458del | In Frame Del (DEL) | VAF 23/59 reads (39%) | called by pindel, varscan2
- GIGYF2 | c.3424A>C p.M1142L | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- GRM6 | c.1745C>T p.S582F | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- IPO9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA0319 | c.1709G>C p.S570T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- OPRPN | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SPTBN5 | c.3233A>G p.E1078G | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- TECTA | c.5514dup p.G1839Rfs*33 | Frame Shift Ins (INS) | VAF 5/52 reads (10%) | called by mutect2, pindel, varscan2
- VWF | c.964del p.Q322Rfs*135 | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | called by mutect2, pindel, varscan2
- ZDHHC18 | c.929A>T p.N310I | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ARV1 | c.747C>G p.V249= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV59618568; called by muse, mutect2, varscan2
- EYA1 | c.711A>G p.A237= | Silent (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- INCENP | c.1951C>T p.L651= (on ENST00000394818 / NM_001040694.2; = p.L647= on NM_020238.3) | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1417162246; called by muse, mutect2, varscan2
- KDM4B | c.1962G>A p.P654= | Silent (SNP) | VAF 80/241 reads (33%) | catalogued as rs778267422; called by muse, mutect2, varscan2
- MARK3 | c.198T>C p.N66= | Silent (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- PITPNM3 | c.2850G>A p.S950= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV99338293; called by muse, mutect2, varscan2
- SCN4A | c.4092C>T p.C1364= | Silent (SNP) | VAF 16/263 reads (6%) | called by muse, mutect2
- SUSD5 | c.1275C>T p.L425= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs777894399; called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622932 C>T | 3'Flank (SNP) | VAF 31/97 reads (32%) | catalogued as COSV57544423; called by muse, mutect2, varscan2
- BAD | c.188-5165C>T | Intron (SNP) | VAF 25/105 reads (24%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3760C>T | Intron (SNP) | VAF 20/72 reads (28%) | catalogued as COSV65184951; called by muse, mutect2, varscan2
